CPTAC case C524103 — Other and unspecified urinary organs — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Other and unspecified urinary organs. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/24350ad9-d6e5-49f0-ab92-f9e53799e685

Demographics
Sex at birth: female; Age at index: 63 years; Vital status: Dead; Days to death: 210 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Urethra; Site of resection or biopsy: Cerebrum; Last known disease status: With tumor; Days to last known disease status: 210 days; Progression or recurrence: yes; Days to recurrence: 36 days; Sites of involvement: Brain, Cerebrum; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 2; Cigarettes per day: 5; Alcohol history: Yes.

Biospecimens (7 samples)
- Samples 1104794, 1104811, 1105204, 1105258, SM-JU33S, SM-JU345 (6 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Left; Preservation method: Snap Frozen.
- Sample 1105274: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
